Surgical pathology report (de-identified scan), TCGA case TCGA-WZ-A8D5, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site  International Genomics Consortium, specimen TCGA-WZ-A8D5-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone

Final Report

DIAGNOSIS

LEFT TESTICLE, RADICAL ORCHITECTOMY:

1. Seminoma, pure
2. Tumor extends into epididymis, base of the spermatic cord, and peri-testicular adipose tissue
3. Surgical margins are negative for tumor
4. Lymphatic/vascular invasion by tumor is present
5. Please see testis cancer staging parameters below

2010 TESTIS CANCER STAGING PARAMETERS

Case number: Patient name:

Final TNM: pT3NXM0

2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Radical Orchiectomy

TUMOR LATERALITY

Left

TUMOR SIZE

10 X 6 X 4.5 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Seminoma, classic type

MARGINS

Uninvolved

MICROSCOPIC TUMOR EXTENSION

Into peritesticular adipose tissue and base of spermatic cord

LYMPHATIC/VASCULAR INVASION

Present

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor invades the spermatic cord with or without vascular/lymphatic invasion)

REGIONAL LYMPH NODES

pNX. (Regional lymph nodes cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

SERUM TUMOR MARKERS

SX. (Serum marker studies not available or performed [Although LDH, HCG, and AFP values may be available, the 'S' designation in AJCC staging

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 4/17/14

[page 2 of 3]
[REDACTED]

specifically refers to post-orchietomy levels. These levels are currently not available])

PATHOLOGIC STAGE Summary

Final TNM: pT3NXM0

2010 stage: I

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

Left testicular tumor

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Testicle and tumor, left

The specimen is received labeled "L testicle and tumor." It consists of a 198 gm, 13 x 7 x 4.8 cm radical orchietomy including enlarged indurated testis (10.5 x 6.5 x 4.6 cm), attached stump of spermatic cord (2.5 x 1.3 x 1.1 cm). The spermatic cord margin is inked yellow and the external surfaces are inked black. Cut surfaces disclose a solid mottled gray-tan tumor mass effacing the testis, with extension through rete testis, into the epididymis at the base of the cord. In addition, the tumor extends through the tunica albuginea into peritesticular soft tissue at the head of the testis. The tumor mass measures 10 x 6 x 4.5 cm, is mottled with yellow-brown areas of softened possible necrosis and hemorrhage, comprising approximately 40-50% of the tumor volume. No normal testis or epididymis is identified.

Photographs of the specimen are taken. Tissue is aliquoted for possible additional ancillary studies.

A representative section of tumor (two pieces) is submitted on one block for frozen microscopy.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Seminoma present, possible mixed germ cell tumor based on gross." is rendered by [REDACTED]

Representative sections are submitted in 18 cassettes as follows:

1. Frozen section residue
2. Spermatic cord margin (inked yellow)
3. Spermatic cord, 1 cm from cassette 2
- 4-5. Tumor possibly effacing epididymis and head of testis/base of cord
- 6-18. Testicular tumor, spanning 10 cm (cassettes 7, 8, 11, 13 and 17 each include black-inked external tissue edge)

This case is accessioned in

Gross dictation by:

MICROSCOPIC

The microscopic appearance substantiates the diagnosis. Immunohistochemical staining for CD30 is performed on block A16 and supports the diagnosis.

Support for the interpretation of this case may have included the use of immunohistochemistry and/or in situ hybridization tests that were performed by [REDACTED] and whose performance characteristics were evaluated by pathologists from [REDACTED]. These tests

[REDACTED]

[page 3 of 3]
[REDACTED]

have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Dictation by: [REDACTED] transcribed by: [REDACTED]

[REDACTED]

COLLECTED: ACCESSIONED: SIGNED: L

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] on - Lab and Collection
Information

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED] on - Order Result History
Report

Lab Status
Order Complete

[REDACTED]

Result Information

Result Date and Time	Status	Provider Status
	Final result	Reviewed

Lab Information

Lab

[REDACTED]

Order Details

Parent Order ID Child Order ID

[REDACTED] [REDACTED]

Entry Date

Specimen Information

Specimen Source	Collection Date	Collection Time
Other		

Audit Trail

Action	User	Date/Time
Order Printed	[REDACTED]	
Order Printed	[REDACTED]	

Status:

This result is currently not released to

[REDACTED]

HI/2AA Discrepancy		✓

[REDACTED]

Source: NCI Genomic Data Commons file 17987e66-e91b-48d2-ad91-5d338d5f7a02 (TCGA-WZ-A8D5.FD7C57A7-936B-4C08-8030-15ECE27FB524.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).